Somatic mutation profile of tumor specimen TCGA-49-6745-01A (aliquot TCGA-49-6745-01A-11D-1855-08) from TCGA case TCGA-49-6745, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 82.5 years (30,133 days).
Specimen TCGA-49-6745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e8d53d-3dc4-4fde-9fe2-f8586469628a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6745-11A (Solid Tissue Normal), aliquot TCGA-49-6745-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15ec8bbf-d413-482f-93c1-4e6ada012b45

The open-access MAF lists 130 somatic variants for this specimen: 100 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 26, Nonsense Mutation 8, Splice Site 3, Intron 2, 5'UTR 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+1G>T p.X1010_splice | Splice Site (SNP) | VAF 25/75 reads (33%) | hotspot (GDC flag); catalogued as rs869320707, COSV59256499, COSV59256681, COSV59259384, COSV59260405; ClinVar: risk factor; called by muse, mutect2, varscan2
- ABCD2 | c.651C>A p.F217L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as COSV58049371, COSV58054547; called by muse, mutect2, varscan2
- ABCG5 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV53209371, COSV53209690; called by muse, mutect2, varscan2
- ABCG5 | c.962G>C p.R321T | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53209384; called by muse, mutect2, varscan2
- AGL | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV54047889; called by muse, varscan2
- AKAP9 | c.10882G>A p.E3628K (on ENST00000359028; = p.E3604K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62338433; called by muse, mutect2, varscan2
- AKR1C3 | c.201C>G p.S67R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs781946721, COSV101003040; called by muse, mutect2, varscan2
- AL645922.1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV54959171; called by muse, mutect2, varscan2
- AMPD2 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56646157; called by muse, mutect2, varscan2
- ANKRD26 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65792782; called by muse, mutect2, varscan2
- ARHGAP17 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV51504769; called by muse, mutect2, varscan2
- BNC1 | c.2319C>A p.N773K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1453233120, COSV61756470; called by muse, mutect2, varscan2
- BVES | c.111G>C p.W37C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58946538; called by muse, mutect2, varscan2
- CACNA1I | c.567C>G p.I189M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60800698; called by muse, mutect2, varscan2
- CFTR | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as CM960283, COSV50040750, COSV50099054; called by muse, varscan2
- CHD7 | c.4732G>A p.D1578N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV71107104; called by muse, mutect2, varscan2
- CHD8 | c.3766C>T p.R1256C (on ENST00000646647 / NM_001170629.2; = p.R977C on NM_020920.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67869650; called by muse, mutect2, varscan2
- CHRNB1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.674); catalogued as COSV53438925; called by muse, mutect2, varscan2
- CNTRL | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs772531958, COSV53043071; called by muse, mutect2, varscan2
- CTNNA2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756543455, COSV100782637, COSV63546169; called by muse, mutect2, varscan2
- DBX1 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV57053383; called by muse, mutect2, varscan2
- DCAF12L1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64421151, COSV64422009; called by muse, mutect2, varscan2
- DHH | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1331311795, COSV99908778; called by muse, mutect2
- DHX36 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV57670827; called by muse, mutect2, varscan2
- DMXL1 | c.4330G>C p.D1444H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV60704614; called by muse, mutect2, varscan2
- DOP1B | c.6324_6326del p.E2108del | In Frame Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs779495484; called by pindel, varscan2
- DYNC1H1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV64134259; called by muse, mutect2, varscan2
- DYNC1H1 | c.9586G>A p.E3196K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64134263; called by muse, mutect2, varscan2
- EIF2B4 | c.1322A>G p.Y441C (on ENST00000347454 / NM_001034116.2; = p.Y440C on NM_015636.3) | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1433783398, CM152532, COSV61456090; called by muse, mutect2, varscan2
- ELP6 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs373089295; called by mutect2, varscan2
- EXOC5 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61770092; called by muse, mutect2, varscan2
- FAM71B | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57227458; called by muse, mutect2, varscan2
- GBA2 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62305229; called by muse, mutect2
- HTRA1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757906111, COSV64563380; called by muse, mutect2, varscan2
- IAPP | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.283); catalogued as COSV99557010; called by muse, mutect2
- IFNA2 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV66505302; called by muse, mutect2
- IKZF2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs754170741, COSV59576449; called by muse, mutect2, varscan2
- ITIH5 | c.823-2A>G p.X275_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as rs1202764368, COSV99904044; called by muse, mutect2, varscan2
- ITPR3 | c.6125C>T p.S2042L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100967601, COSV65405553; called by muse, mutect2, varscan2
- KAT6A | c.4330C>T p.Q1444* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV55902508; called by muse, mutect2
- LGR5 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV57002021, COSV57004906; called by muse, mutect2
- LRRK2 | c.6068A>G p.Y2023C | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV54143172; called by muse, mutect2, varscan2
- MAP3K8 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV53918641; called by muse, mutect2, varscan2
- MGA | c.2840C>G p.S947* | Nonsense Mutation (SNP) | VAF 45/165 reads (27%) | catalogued as COSV54948648; called by muse, mutect2, varscan2
- MIGA2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.249); catalogued as COSV52975764; called by muse, mutect2
- MOV10L1 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | catalogued as COSV53167220, COSV53167920; called by muse, mutect2, varscan2
- MTO1 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64773045; called by muse, mutect2, varscan2
- MUC16 | c.34033G>C p.E11345Q | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV67443816; called by muse, mutect2
- MYO15A | c.3412C>T p.Q1138* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1225677143, COSV52751554; called by muse, varscan2
- NAA16 | c.1626G>C p.L542F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65064119; called by muse, mutect2, varscan2
- NALCN | c.2883A>G p.I961M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51916901; called by muse, mutect2, varscan2
- NAXD | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV99959483, COSV99959543; called by muse, mutect2, varscan2
- NLRP3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100275619, COSV60219647; called by muse, mutect2
- NOVA2 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV54355892; called by muse, mutect2
- NRK | c.1744C>G p.R582G | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV54589566, COSV54599067; called by muse, mutect2
- ODF2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV63545701; called by muse, mutect2
- OR2A25 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs749595169, COSV68716835, COSV68717364; called by muse, mutect2, varscan2
- OR6C68 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV101110015; called by muse, mutect2
- OR7D2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); catalogued as rs199962381, COSV60139107; called by muse, mutect2
- PCLO | c.10930G>A p.E3644K | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61615258; called by muse, mutect2
- PLA2R1 | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV51774776; called by muse, mutect2, varscan2
- PLXNA4 | c.4287-1G>A p.X1429_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | catalogued as COSV58104227; called by muse, mutect2
- PRRC2C | c.2452G>A p.E818K (on ENST00000367742; = p.E816K on NM_015172.4) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV100145058, COSV58900778; called by muse, mutect2
- PTGER4 | c.1179G>C p.Q393H | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV56720016; called by muse, mutect2
- RET | c.2672C>A p.S891* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV60686623, COSV60686675; called by muse, mutect2, varscan2
- ROBO1 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV71391575; called by muse, mutect2, varscan2
- ROBO2 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.818); catalogued as rs1480209531, COSV59895971; called by muse, mutect2, varscan2
- SAP30BP | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV53126648; called by muse, mutect2
- SEMA3A | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54861395; called by muse, mutect2, varscan2
- SLC39A5 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as COSV57190507; called by muse, mutect2, varscan2
- SMAD2 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50992902, COSV51028616; called by muse, mutect2, varscan2
- SMPD1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.035); catalogued as COSV100192489; called by muse, mutect2, varscan2
- SOS1 | c.2639C>T p.S880L | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67673769; called by muse, mutect2, varscan2
- SPEG | c.8941C>T p.R2981* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | catalogued as rs767645269, COSV56662833; called by mutect2, varscan2
- STK11IP | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs531254740, COSV55251890, COSV99822503; called by muse, mutect2, varscan2
- STXBP5 | c.3262G>A p.E1088K (on ENST00000321680 / NM_001127715.2; = p.E1052K on NM_139244.4) | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51647748; called by muse, mutect2, varscan2
- SYNCRIP | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.161); catalogued as COSV62286574; called by muse, mutect2, varscan2
- SYNE1 | c.5230G>A p.E1744K (on ENST00000367255 / NM_182961.4; = p.E1751K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.227); catalogued as rs540091060, COSV54903395; ClinVar: uncertain significance; called by muse, mutect2
- TMF1 | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68373399; called by muse, mutect2
- TRIM51 | c.1004C>G p.A335G | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55263517; called by muse, mutect2, varscan2
- TRPV5 | c.1761G>T p.Q587H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54682997; called by muse, mutect2
- TTN | c.3553C>T p.Q1185* (on ENST00000591111; = p.Q1139* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV59880924; called by muse, mutect2
- TUBB2B | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99455335; called by muse, mutect2, varscan2
- UBE3D | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52751507; called by muse, mutect2, varscan2
- UGT2B17 | c.1117A>T p.I373L | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100497182; called by muse, mutect2, varscan2
- VPS13B | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62016012; called by muse, mutect2, varscan2
- YIPF3 | c.906G>A p.G302= | Splice Region (SNP) | VAF 20/83 reads (24%) | catalogued as rs774947013, COSV58303476; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1205449387, COSV54293173; called by muse, mutect2
- ZFHX4 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV50488261; called by muse, mutect2, varscan2
- ZIK1 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56736412; called by muse, mutect2, varscan2
- ZKSCAN1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV100164142, COSV100164338; called by muse, mutect2
- ZMIZ1 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1477891777, COSV57889511; called by muse, mutect2, varscan2
- ZNF189 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV52274270; called by muse, mutect2, varscan2
- ZNF398 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60064370, COSV60064487; called by muse, mutect2, varscan2
- ZNF398 | c.1570G>C p.E524Q (on ENST00000475153 / NM_170686.3; = p.E353Q on NM_020781.4) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV60064495; called by muse, mutect2
- ZNF660 | c.186T>A p.S62R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as COSV100502666; called by muse, mutect2, varscan2
- ZPBP | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV50422449, COSV50427195; called by muse, mutect2
- ZSCAN5A | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV54223663; called by muse, mutect2, varscan2
- GDF10 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.425); called by mutect2, varscan2
- PPIAL4A | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2913C>T p.P971= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV65888207; called by muse, mutect2, varscan2
- AGL | c.2115C>A p.I705= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV54047902; called by muse, varscan2
- CDH4 | c.1557C>T p.G519= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1449979913, COSV64641617; called by muse, mutect2, varscan2
- CDHR3 | c.2214C>T p.I738= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58413614; called by muse, mutect2, varscan2
- CENPC | c.870G>A p.S290= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs781649108, COSV99893670; called by muse, mutect2, varscan2
- CLPTM1L | c.528G>A p.L176= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV57989296; called by muse, mutect2, varscan2
- CNTN1 | c.3054C>T p.F1018= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs754501613, COSV61636041; called by muse, mutect2
- COL4A2 | c.789G>A p.A263= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs778452032, COSV100847318, COSV64624722; called by muse, mutect2, varscan2
- DNAH8 | c.11073C>G p.L3691= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV59423801; called by muse, mutect2, varscan2
- EPX | c.966G>A p.S322= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs201284086, COSV56594820; called by muse, mutect2, varscan2
- EVC | c.2196G>A p.V732= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53829105; called by muse, mutect2
- FAM110B | c.138G>A p.K46= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV64063158; called by muse, mutect2
- FBXO47 | c.219A>C p.T73= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV65241123; called by muse, mutect2, varscan2
- FERMT2 | c.1467T>G p.V489= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as COSV58405062; called by muse, mutect2, varscan2
- GP2 | c.396C>T p.I132= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV56891959; called by muse, mutect2, varscan2
- H2BC17 | c.261C>G p.R87= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV100377521; called by muse, mutect2
- IMMT | c.261G>A p.E87= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs766251899, COSV54485398; called by muse, mutect2, varscan2
- KIR3DL1 | c.1320T>A p.V440= | Silent (SNP) | VAF 55/460 reads (12%) | catalogued as COSV58487799; called by muse, mutect2, varscan2
- MDH1B | c.375G>A p.L125= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1275699278, COSV65588486; called by muse, mutect2, varscan2
- MDN1 | c.4552C>T p.L1518= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV101020876, COSV65517019; called by muse, mutect2
- POPDC2 | c.699C>T p.F233= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV51739736; called by muse, mutect2, varscan2
- RAP1GAP | c.444C>T p.T148= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs375841009; called by muse, mutect2, varscan2
- SNRNP35 | c.93C>T p.V31= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV63471791; called by muse, mutect2, varscan2
- SRPRA | c.1272C>T p.C424= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs375322300; called by muse, mutect2, varscan2
- SWT1 | c.1314A>G p.L438= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV62252833; called by muse, mutect2, varscan2
- UNC79 | c.5578C>T p.L1860= (on ENST00000393151 / NM_001346218.2; = p.L1683= on NM_020818.5) | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV56373333; called by muse, mutect2, varscan2
- AC024940.1 | n.2776G>C | RNA (SNP) | VAF 29/456 reads (6%) | catalogued as rs1239971897; called by muse, mutect2
- C5orf58 | c.-4A>C | 5'UTR (SNP) | VAF 26/76 reads (34%) | catalogued as COSV69758857; called by muse, mutect2, varscan2
- PHB2 | c.711+206C>G | Intron (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99781003; called by muse, mutect2, varscan2
- SKAP1 | c.978+5978C>T | Intron (SNP) | VAF 16/56 reads (29%) | catalogued as COSV61143971; called by muse, mutect2, varscan2
